Surgical pathology report (de-identified scan), TCGA case TCGA-RC-A6M3, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site University of Utah, specimen TCGA-RC-A6M3-01A (Primary Tumor).

[page 1 of 3]
SP Final Report

* Final Report *

Result Type: SP Final Report
Service Date: [REDACTED]
Result Status: Final
Result Title: Surg Path Final Report
Authored By: [REDACTED]
Electronically Signed By: [REDACTED]

* Final Report *

Diagnosis

1. LIVER, EXTENDED RIGHT LOBE, RESECTION:

- HEPATOCELLULAR CARCINOMA, GRADE III, 15.2 X 13.5 X 13.2 CM.
- SURGICAL MARGINS ARE NEGATIVE FOR CARCINOMA.
- ADJACENT LIVER SHOWING CHOLESTASIS AND FIBROSIS.
- DISTANT NON-NEOPLASTIC LIVER SHOWING NO PATHOLOGIC ABNORMALITY.
- SEE SYNOPTIC REPORT AND COMMENT.

2. GALLBLADDER, CHOLECYSTECTOMY:

- UNREMARKABLE GALLBLADDER.
- ONE BENIGN LYMPH NODE, NEGATIVE FOR MALIGNANCY (0/1).
- NO EVIDENCE OF MALIGNANCY.

Signature Line

I certify that I personally conducted the
diagnostic evaluation on the above specimens
and have rendered the above diagnosis(es):

[REDACTED]
electronic signature

Department of Pathology

For questions regarding this case, call

Clinical History

Liver tumor

Submitting Physician

Printed by:
Printed on:

Page 1 of 3
(Continued)

ICD O-3
Carcinoma, hepatocellular NOS
8170/3
Site Liver C22.0
JW 7/24/13

[page 2 of 3]
SP Final Report

* Final Report *

Sorenson/Surgery

Comments

The tumor has an overall trabecular architecture with solid sheets, nests and cords of tumor. The cells are high grade but generally recognizable as hepatocytes (Grade III). In some microscopic fields there is prominent cytologic and nuclear pleomorphism, with multinucleated cells with bizarre nuclei. There is no evidence of sarcomatoid differentiation. The tumor shows focal microscopic vascular invasion; however, per the staging guidelines, since there is no evidence of involvement of a "major" branch of the portal or hepatic vein, the tumor is staged as pT2.

Resident Involved.

Microscopic Examination

Performed.

ACCESSION

Synoptic Report

Primary tumor diagnosis: Hepatocellular carcinoma
Tumor grade: Poorly differentiated (grade III)
Tumor size: 15.2 x 13.5 x 13.2 cm

Extent and location of tumor:

x tumor is solitary and confined to the right lobe of the liver

Margins of excision:

x no tumor identified at margins
x tumor is 0.35 cm from the parenchymal resection margin
x tumor is present beneath the hepatic capsule but not on the surface
x hepatic capsule is free of tumor

Lymph node: 1 number examined
0 number involved

pT2 N0 Mx

Gross Description

The case is received in two parts each labeled with the patient's name and medical record number.

Part one is received fresh and subsequently placed in formalin labeled "#1 extended right lobe", and consists of a 2600 gram, 26.1 x 20.3 x 11.7 cm unoriented, previously incised partial hepatectomy. The glisson's capsule is mild tan-purple and smooth with a minimal amount of adherent blood clot. There is a roughened margin of resection where the specimen has been previously incised and shows yellow-white firm nodular tissue grossly consistent with

Printed by:
Printed on:

Page 2 of 3
(Continued)

[page 3 of 3]
SP Final Report

* Final Report *

tumor on the cut surfaces. There are no hilar vessel margins identified. Sectioning reveals a 15.2 x 13.5 x 13.2 cm fairly well defined tan-white-yellow soft to rubbery mass that abuts the glisson's capsule but does not penetrate through and is 0.4 cm focally from the inked margin of resection. Additionally the mass has a tan-green firm component to it that also abuts the glisson's capsule and is 3.9 cm from the inked margin of resection. The involved liver parenchyma is red-brown and glistening with no additional lesions present. Representative sections are submitted as follows: 1A-1B mass to closest margin of resection, 1C-1E mass to glisson's capsule, 1F-1H additional mass, 1I described firmer green component of mass to glisson's capsule, 1J-1L representative section of firmer green component of mass, 1M uninvolved appearing liver.

Part two is received in formalin labeled "#2 gallbladder", and consists of 6.2 x 3.7 x 1.0 cm intact gallbladder with a 0.6 cm in length x 0.4 cm in diameter patent cystic duct. The serosa is tan-yellow to green and ranges from smooth to wrinkled. Opening of the lumen reveals a minimal amount of yellow-green viscous bile. There are no choleliths identified. There are no intraluminal masses present. The wall ranges from 0.1 to 0.3 cm in thickness. The mucosa is bile stained green and velvety. There is a 0.5 cm possible lymph node identified adjacent to the cystic duct. Representative sections are submitted in cassette 2A to include the bile duct margin and probable lymph node.

Signature Line

Printed by:
Printed on:

Page 3 of 3
(End of Report)

Site of Discrepancy		

Source: NCI Genomic Data Commons file 33abc771-768e-48fd-ab5c-8698a03dffd8 (TCGA-RC-A6M3.E01BF72F-DD73-46D9-8767-A90593DB371B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).